Gene-level copy-number profile of tumor specimen TCGA-BR-4367-01A from TCGA case TCGA-BR-4367, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; Tumor grade: G3; Age at diagnosis: 78.9 years (28,817 days).
Specimen TCGA-BR-4367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.399bf5be-4a31-405d-9060-f517d1a6e9d4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-4367-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ba1a37f3-1a98-4055-b52f-5be23fdae54b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 436; copy number 2: 16,020; copy number 3: 28,320; copy number 4: 10,723; copy number 5: 3,783; copy number 6: 253; copy number 7: 49; copy number 8: 124; copy number 9: 10; copy number 10: 14; copy number 12: 54; copy number 62: 3; copy number 63: 4; copy number 65: 1; copy number 72: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BR-4367-01): tumor purity 0.44, ploidy 2.96, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:138,868,921–138,875,368, 1 gene: LRRTM2.
- chr5:139,012,329–139,051,203, 3 genes: RNA5SP194, AC011405.1, RPL12P21.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 265 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:8,750,430–9,369,532, 24 genes, copy number 7: RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD, SPSB1.
- chr1:10,472,288–11,319,093, 25 genes, copy number 7 (within-gene range 3–7): PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1, HSPE1P24, C1orf127, CFL1P6, TARDBP, AL109811.3, MASP2, AL109811.2, SRM, EXOSC10, AL109811.1, EXOSC10-AS1, MTOR, MTOR-AS1, RNU6-537P, ANGPTL7, RNU6-291P, RPL39P6, UBIAD1, UBE2V2P3, AL031291.1.
- chr11:3,469,319–3,855,509, 21 genes, copy number 12: AC127526.1, AC127526.2, AC127526.4, SNRPCP5, RPS3AP39, RPS24P14, AP006294.2, AP006294.1, OR7E117P, TRPC2, ART5, ART1, Y_RNA, Y_RNA, CHRNA10, NUP98, RNU6-1143P, RNU7-50P, PGAP2, RHOG, STIM1-AS1.
- chr11:3,854,612–3,922,703, 4 genes, copy number 12: AC090587.1, MIR4687, PPIAP40, AC087441.1.
- chr12:9,817,350–9,932,370, 6 genes, copy number 72 (within-gene range 3–72): GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2, CLEC2A.
- chr12:12,473,282–12,568,776, 3 genes, copy number 62: DUSP16, AC007619.1, AC092824.1.
- chr12:25,195,216–25,250,936, 4 genes, copy number 63 (within-gene range 4–63): ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:41,829,898–43,163,110, 29 genes, copy number 8–10: AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461.
- chr12:46,183,063–46,270,017, 1 gene, copy number 65 (within-gene range 3–65): SLC38A1.
- chr12:53,935,328–54,803,589, 60 genes, copy number 8: HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C, Y_RNA, SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1, VDAC1P5.
- chr14:30,559,158–32,882,830, 49 genes, copy number 8 (within-gene range 4–8): G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4, AP4S1, HECTD1, RPL21P5, RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P, AL355112.1, LINC02313, AL352984.2, AL352984.1, ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1, AKAP6, AL136298.1, RN7SL660P, MTCO1P2, AL049781.1.
- chr18:21,650,901–23,026,488, 39 genes, copy number 9–12: ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 401. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
